Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4FK, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4FK-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Patient Name:	Service:	Accession #:
MRN:	Visit #:	Collected:
DOB:		Received:
Gender:	Location:	Reported:
Ordering MD:	Facility:	
Copy To:		

Specimen(s) Received

1. Thyroid: Right subtotal stitch superior

Diagnosis

Papillary carcinoma, oncocytic variant 2.6 cm right; nonspecific chronic thyroiditis: Thyroid, right hemithyroidectomy specimen.

Comment

This case has been seen in consultation with _____ and he agrees with the interpretation and diagnosis.

Synoptic Data

Procedure:	Right hemithyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	5.0 cm
	2.6 cm
	2.0 cm
	Isthmus +/- pyramidal lobe:
	2.5 cm
	1.6 cm
	0.8 cm
Specimen Weight:	16.9 g
Tumor Focality:	Unifocal

----- DOMINANT TUMOR -----

Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 2.6cm
	Additional dimension: 2.2 cm
	Additional dimension: 1.9 cm

Histologic Type:	Papillary carcinoma, oncocytic or oxyphilic variant
	Follicular architecture per TSS, follicular variant = 100%
	Other architecture: focal solid and trabecular growth
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated

1CB-0-3
carcinoma, papillary, follicular
variant 0340/3

Site: thyroid, NOS C73.9

hw
10/2/12

[page 2 of 2]
Surgical Pathology Consultation Report

Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: Not applicable
Primary Tumor (pT): pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN): pNX: Regional lymph nodes cannot be assigned
Number of regional lymph nodes examined: 0
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Thyroiditis, focal (nonspecific)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "right subtotal thyroid, stitch superior", consists of a right hemithyroidectomy specimen that is oriented with a stitch, superior and weighs 16.9 g. The lobe measures 5.0 cm SI x 2.6 cm ML x 2.0 cm AP and the isthmus measures 2.5 SI x 1.6 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions and are painted with liquid bluing. No parathyroid glands and/or lymph nodes are identified grossly. The right lobe contains a lower pole well delineated, tan and focally hemorrhagic nodule(s) that measure 2.6 cm SI x 2.2 cm ML x 1.9 cm AP. The remainder of the thyroid tissue is grossly normal. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-M lobe, superior to inferior
1N-P isthmus

Dual/Synchronous Primary (noted)		X

Source: NCI Genomic Data Commons file ebb840a7-95ae-4f30-bf2d-905cb171c4a1 (TCGA-EM-A4FK.EF94D807-0D05-49D5-B5B3-A9731D861BF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).